Gene-level copy-number profile of tumor specimen TCGA-F2-A8YN-01A from TCGA case TCGA-F2-A8YN, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 76.8 years (28,047 days).
Specimen TCGA-F2-A8YN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.4ed9c126-086f-4ac7-a9bc-6ccda52506f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F2-A8YN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4e00a87-276a-4a79-a4f6-7a839c4f4212

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 15,838; copy number 2: 43,231; copy number 3: 621; copy number 5: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F2-A8YN-01A-11D-A376-01): tumor purity 0.58, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:107,152,562–107,459,564, 1 gene (within-gene range 0–2): PDSS2.
- chr6:107,229,759–107,230,152, 1 gene: RPS24P12.
- chr6:107,509,803–107,511,721, 1 gene: AL121957.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 119 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:28,732,017–30,326,134, 119 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
